Somatic mutation profile of tumor specimen TCGA-S9-A7R1-01A (aliquot TCGA-S9-A7R1-01A-12D-A34J-08) from TCGA case TCGA-S9-A7R1, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 35.1 years (12,828 days).
Specimen TCGA-S9-A7R1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0186cff7-7fc8-48d1-9539-b034424ce762.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-S9-A7R1-10A (Blood Derived Normal), aliquot TCGA-S9-A7R1-10A-01D-A34M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8662604b-6479-4631-997f-0339c1dfa45c

The open-access MAF lists 18 somatic variants for this specimen: 17 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 13, Nonsense Mutation 2, In Frame Del 1, Frame Shift Del 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 44/110 reads (40%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ANXA5 | c.314C>A p.T105K | Missense Mutation (SNP) | VAF 48/125 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99634146; called by muse, mutect2, varscan2
- BLM | c.2239A>G p.T747A | Missense Mutation (SNP) | VAF 19/125 reads (15%) | SIFT tolerated (0.85); PolyPhen benign (0.001); catalogued as COSV100756895; called by muse, mutect2, varscan2
- DCLRE1A | c.1744G>A p.G582R | Missense Mutation (SNP) | VAF 12/208 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.042); catalogued as rs17855759; called by muse, mutect2
- FOLR1 | c.180G>A p.W60* | Nonsense Mutation (SNP) | VAF 63/136 reads (46%) | catalogued as COSV100398496; called by muse, mutect2, varscan2
- GALNT12 | c.1600C>T p.Q534* | Nonsense Mutation (SNP) | VAF 11/89 reads (12%) | catalogued as COSV100899033; called by muse, mutect2, varscan2
- GDAP2 | c.1463A>G p.Y488C | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs1425942433, COSV101032291; called by muse, mutect2, varscan2
- IL1R1 | c.547G>A p.V183M | Missense Mutation (SNP) | VAF 56/101 reads (55%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.857); catalogued as rs767728778, COSV52108792; called by muse, mutect2, varscan2
- OR51E2 | c.85C>T p.P29S | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101211305; called by muse, mutect2, varscan2
- PTCHD1 | c.758C>T p.T253M | Missense Mutation (SNP) | VAF 12/173 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as rs1467984927, COSV101037215; called by muse, mutect2
- SEL1L | c.2132A>G p.K711R | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.742); catalogued as COSV100377625; called by muse, mutect2, varscan2
- UTP6 | c.910C>T p.R304W | Missense Mutation (SNP) | VAF 54/146 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as rs772746694, COSV99911776; called by muse, mutect2, varscan2
- ZBTB11 | c.794G>A p.S265N | Missense Mutation (SNP) | VAF 40/105 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100465079; called by muse, mutect2, varscan2
- ZNF597 | c.955G>A p.D319N | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT tolerated (0.41); PolyPhen benign (0.014); catalogued as rs1181677149, COSV57085057; called by muse, mutect2
- ZNF786 | c.2087G>A p.G696D | Missense Mutation (SNP) | VAF 18/322 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.739); catalogued as COSV100302644; called by muse, mutect2
- CDNF | c.227del p.G76Efs*10 | Frame Shift Del (DEL) | VAF 12/145 reads (8%) | called by mutect2, pindel
- PCLO | c.5746_5748del p.E1916del | In Frame Del (DEL) | VAF 6/46 reads (13%) | called by pindel, varscan2
- SSX5 | c.192G>A p.K64= (on ENST00000347757 / NM_175723.1; = p.K105= on NM_021015.4) | Silent (SNP) | VAF 11/118 reads (9%) | catalogued as COSV100308599, COSV100308702; called by muse, mutect2
